TCGA case TCGA-NC-A5HG — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - CHUV. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c179d6b1-6182-48b8-a376-3133e0dec278

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Switzerland; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.2 years (21,608 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,963 days (5.4 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Vinorelbine Tartrate; Days to treatment start: 37 days; Days to treatment end: 107 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 125 days; Days to treatment end: 163 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.

Follow-up (4 entries)
- Days to follow up: 1,548 days (4.2 years); Disease response: Tumor Free.
- Days to follow up: 1,575 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,963 days (5.4 years); Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 77; FEV1/FVC after bronchodilator (%): 68; FEV1/FVC before bronchodilator (%): 63; FEV1 after bronchodilator (% of reference): 90; FEV1 before bronchodilator (% of reference): 85.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 80; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 2008.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NC-A5HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-NC-A5HG-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-NC-A5HG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-NC-A5HG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Basaloid Squamous Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Navelbine.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,963 days; disease-specific survival: no event (censored), 1,963 days; disease-free interval: no event (censored), 1,963 days; progression-free interval: no event (censored), 1,963 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NC-A5HG-01A-11D-A26L-01): tumor purity 0.75, ploidy 3.53, whole-genome doublings 1.
